Somatic mutation profile of tumor specimen TCGA-J9-A52D-01A (aliquot TCGA-J9-A52D-01A-11D-A29Q-08) from TCGA case TCGA-J9-A52D, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.2 years (26,023 days).
Specimen TCGA-J9-A52D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61b6bade-2010-4678-a1f2-72854629cd9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A52D-10A (Blood Derived Normal), aliquot TCGA-J9-A52D-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18987881-ec99-40e2-94a9-ae43369ddfdc

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 24, Silent 11, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 60/132 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARL1 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV55370821; called by muse, mutect2, varscan2
- BAMBI | c.155T>A p.F52Y | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as rs764901219, COSV65003319; called by muse, mutect2, varscan2
- BCAS4 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV52813760; called by muse, mutect2, varscan2
- CDH12 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201923, COSV66434244; called by muse, mutect2
- CFH | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373339058; called by muse, mutect2, varscan2
- CHD1 | c.1834G>C p.G612R | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV52343525; called by muse, mutect2, varscan2
- DNAJC24 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV71938841; called by muse, mutect2, varscan2
- DPY19L2 | c.2268G>T p.K756N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs759187189, COSV61040380, COSV61044708; called by mutect2, varscan2
- DUS3L | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs776687007, COSV57833114; called by muse, mutect2, varscan2
- ELN | c.1867G>A p.A623T (on ENST00000320399 / NM_001278939.1; = p.A590T on NM_000501.4) | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs868932429, COSV52713778; called by muse, mutect2, varscan2
- ERC1 | c.1277T>G p.M426R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61698158; called by muse, mutect2, varscan2
- KDM4A | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64960322, COSV64960488; called by muse, mutect2, varscan2
- LRRN3 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57822707; called by muse, mutect2, varscan2
- MTCP1 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62900261; called by muse, mutect2, varscan2
- MYOT | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53515876; called by muse, mutect2, varscan2
- RCOR2 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56851067; called by muse, mutect2, varscan2
- RPA4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61285823; called by muse, mutect2, varscan2
- RTTN | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV55349686; called by muse, mutect2
- RXFP3 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 66/132 reads (50%) | catalogued as COSV57507331; called by muse, mutect2, varscan2
- SLC4A1 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs780297314, COSV52259143; called by muse, mutect2, varscan2
- SPTBN1 | c.5946C>G p.H1982Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV61692086; called by muse, mutect2, varscan2
- ZNF106 | c.4256G>A p.S1419N | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55520377; called by muse, mutect2, varscan2
- ZNF233 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61934336; called by muse, mutect2, varscan2
- ZNF618 | c.2410G>T p.V804L (on ENST00000374126 / NM_001318042.2; = p.V711L on NM_133374.2) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55927076; called by muse, mutect2
- AKAP4 | c.2435_2437del p.A812del | In Frame Del (DEL) | VAF 56/74 reads (76%) | called by pindel, varscan2
- C20orf96 | c.758del p.K253Rfs*18 (on ENST00000360321 / NM_153269.3; = p.K252Rfs*18 on NM_080571.1) | Frame Shift Del (DEL) | VAF 109/289 reads (38%) | called by mutect2, pindel, varscan2
- CDC20B | c.293_294insGA p.Y98* | Nonsense Mutation (INS) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.717del p.S240Afs*13 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | called by mutect2, pindel, varscan2
- CTDSP1 | c.721_723del p.F241del | In Frame Del (DEL) | VAF 54/150 reads (36%) | called by pindel, varscan2
- CYP2A6 | c.1277del p.S426Mfs*64 | Frame Shift Del (DEL) | VAF 65/163 reads (40%) | called by mutect2, pindel, varscan2
- AKAP4 | c.2454A>T p.V818= | Silent (SNP) | VAF 64/74 reads (86%) | catalogued as COSV62075224; called by muse, varscan2
- CTPS1 | c.1683C>G p.L561= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV101009299, COSV65453639; called by muse, mutect2, varscan2
- DCLK1 | c.1284C>A p.G428= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV55202153; called by muse, mutect2, varscan2
- DNAH17 | c.8094C>T p.D2698= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs189793617; called by muse, mutect2, varscan2
- DNAH17 | c.1008C>A p.V336= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV101101678, COSV67759307; called by muse, mutect2, varscan2
- ECI1 | c.516C>T p.Y172= | Silent (SNP) | VAF 77/148 reads (52%) | catalogued as COSV57044649; called by muse, mutect2, varscan2
- IRF9 | c.426G>A p.R142= | Silent (SNP) | VAF 87/202 reads (43%) | catalogued as COSV60703125, COSV60703708; called by muse, mutect2, varscan2
- KLK15 | c.216G>C p.L72= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV56827940; called by muse, mutect2
- NBAS | c.4854C>T p.H1618= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs371291813; ClinVar: likely benign; called by muse, mutect2, varscan2
- OGDHL | c.1344G>A p.P448= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs770910107, COSV100934478, COSV65103977; called by muse, mutect2, varscan2
- UCKL1 | c.1224C>T p.P408= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs370105526, COSV100694139; called by muse, mutect2, varscan2
